Somatic mutation profile of tumor specimen TARGET-10-PAPICC-09A (aliquot TARGET-10-PAPICC-09A-01D) from TARGET case TARGET-10-PAPICC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,508 days).
Specimen TARGET-10-PAPICC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15675fd9-3649-4537-9f26-024165ba8846.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPICC-10A (Blood Derived Normal), aliquot TARGET-10-PAPICC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b0672f5-c902-4191-9f2a-45e146b349d4

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 4, Silent 2, 3'UTR 1, 5'UTR 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP29 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.211); catalogued as rs1212156200, COSV53118102; called by muse, mutect2
- CFAP46 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs915751600; called by muse, mutect2
- SMARCA5 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV51644451; called by muse, mutect2, varscan2
- DOCK5 | c.1537G>T p.V513F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.091); called by muse, varscan2
- KRAS | c.184_185insGACCAGTACCCGCCCCCC p.E62delinsGPVPAPQ | In Frame Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, varscan2
- MYC | c.172_175del p.T58Rfs*44 (on ENST00000377970; = p.T73Rfs*44 on NM_002467.6) | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by pindel*, varscan2
- TLL1 | c.1619A>G p.D540G | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- HHEX | c.417C>T p.G139= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs755244382; called by muse, mutect2, varscan2
- SPTBN2 | c.1506C>T p.I502= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs763934297, COSV59452254; called by muse, mutect2, varscan2
- CPLANE1 | c.*1886G>T | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- EML1 | c.519-5273C>T | Intron (SNP) | VAF 6/76 reads (8%) | catalogued as rs1335960879; called by muse, mutect2
- OR5V1 | c.-6G>A | 5'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as rs374250981; called by muse, mutect2, varscan2
- RALYL | c.257-68613G>A | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as rs760135376, COSV72825813; called by muse, mutect2, varscan2
- SPNS2 | c.1608-133T>C | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- SPPL2B | c.956+680C>A | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
